Gene-level copy-number profile of tumor specimen TCGA-TQ-A7RK-02A from TCGA case TCGA-TQ-A7RK, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 29.4 years (10,742 days).
Specimen TCGA-TQ-A7RK-02A: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LGG.9dabc0dc-9b5b-4245-aaff-8016cbd83f8f.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-TQ-A7RK-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 350 have no estimate.
https://portal.gdc.cancer.gov/files/fe58ad27-49bd-4b7d-8685-5ac7154c603b

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,384; copy number 1: 762; copy number 2: 54,684; copy number 3: 1,615; copy number 4: 826; copy number 5: 2.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:131,596,857–131,597,115, 1 gene: AC140063.1.
- chr13:70,564,267–70,564,437, 1 gene: AL445264.1.
- chr16:86,081,409–86,089,526, 1 gene: AC135012.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr17:71,011,997–71,202,203, 2 genes, copy number 5: AC005181.1, CASC17.

Autosomal genes at a single copy (total copy number 1): 748. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
